CCDI case PBCCVE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ce84540e-c427-46ca-866a-091bfefdc35b

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 1.5 years (559 days).

Biospecimens (3 samples)
- Sample 0DP4OY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP4PC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DP4Q1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
